CPTAC case C3L-08548 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/31867570-3c3c-4a03-aafe-0d3d2517e60b

Demographics
Sex at birth: male; Race: white; Year of birth: 1935; Vital status: Dead; Days to death: 329 days; Year of death: 2022; Cause of death: Cancer Related; Country of birth: Serbia.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Body of stomach; Age at diagnosis: 86.2 years (31,467 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC clinical M: M1; AJCC pathologic T: T4a; AJCC pathologic N: N3b; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G3; Residual disease: R1; Last known disease status: With tumor; Days to last known disease status: 329 days; Progression or recurrence: no; Days to last follow up: 329 days; Tumor focality: Multifocal.
   Pathology details: Greatest tumor dimension: 18 cm; Lymph node involvement: Positive; Lymph nodes positive: 32; Lymph nodes tested: 42.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Pembrolizumab; Days to treatment start: 41 days; Days to treatment end: 309 days; Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Days to follow up: 329 days; Disease response: Progressive Disease; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 8; Cigarettes per day: 20; Tobacco smoking onset year: 1957; Tobacco smoking quit year: 1965; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 8.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-08548-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 9 days; Initial weight: 480 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-08548-21: Section location: Body; Percent tumor nuclei: 75; Percent necrosis: 0.
- Sample C3L-08548-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 9 days; Method of sample procurement: Blood Draw.
